Somatic mutation profile of tumor specimen TARGET-20-PASHWN-09A (aliquot TARGET-20-PASHWN-09A-01D) from TARGET case TARGET-20-PASHWN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,606 days).
Specimen TARGET-20-PASHWN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16d382f2-8d37-4428-b699-3831a536ca79.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASHWN-14A (Bone Marrow Normal), aliquot TARGET-20-PASHWN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c82f50b8-8ac1-43d3-9f24-01588b64bca2

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 36/81 reads (44%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 31/163 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
